Somatic mutation profile of tumor specimen BA3433D (aliquot aq-BA3433D) from BEATAML1.0 case 2681, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,188 days).
Specimen BA3433D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0412a58-fef0-456f-8a9d-f82898620a57.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3313D (Solid Tissue Normal), aliquot aq-BA3313D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49c697ec-4f53-4830-a85c-3180bdc20131

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC14B | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1302463517; called by muse, mutect2
- PLXNA4 | c.4780G>A p.V1594M | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as rs529500573, COSV58167212; called by muse, mutect2
